Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A67T, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A67T-01A (Primary Tumor).

[page 1 of 5]
MRN
Name
Encounter Number

Gender M
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Correction to results

Results

Correction

Source of Specimen

- A. TISSUE OVER PROSTATE-
- B. RIGHT EXTENDED PELVIC LYMPH NODE DISSECTION-
- C. PROSTATE GLAND SEMINAL VESICLES / VAS DEFERENS-

FINAL DIAGNOSIS:

- A. TISSUE OVER PROSTATE-
FATTY TISSUE, NO TUMOR SEEN.
- B. RIGHT EXTENDED PELVIC LYMPH NODE DISSECTION-
EIGHT LYMPH NODES, NEGATIVE FOR TUMOR.
- C. PROSTATE GLAND SEMINAL VESICLES / VAS DEFERENS-
ADENOCARCINOMA OF PROSTATE.

path ICD-O-3
ACF Adenocarcinoma, NOS 8140/3
Adenocarcinoma, Gleason 8140/3
Site: Prostate NOS C61.9
4/25/13

TUMOR SITE: LEFT AND RIGHT PROSTATE, MOSTLY IN PERIPHERAL ZONE.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 47 GRAMS. SIZE: 3.5 x 3.5 x 3 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 4 = 7/10.

TERTIARY PATTERN: NOT SEEN.

SEVERITY IN EXTENT OF TUMOR: 3/5.

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue involvement).

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): IS PRESENT, 1.1 CM IN SIZE.

Prepared for

Criteria	4/25/13	Y	AM	✓

[page 2 of 5]
TREATMENT EFFECT ON CARCINOMA: NOT IDENTIFIED.

TNM STAGE: AT LEAST pT2c, pN0, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

PERINEURAL INVASION: PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

MARGIN STATUS:

POSITIVE INKED MARGINS: RIGHT POSTERIOR PROSTATE, SEE NOTE.
OTHER MARGINS ARE CLEAR.

NOTE: THE CAPSULE OF THE POSITIVE MARGIN APPEARS TO BE DISRUPTED
BY AN IATROGENIC INCISION. THERE IS NO EXTRAPROSTATIC INVASION
SEEN ELSEWHERE. FURTHER CLINICAL CORRELATION IS NEEDED.

Signature

Case Clinical Information
PROSTATE CANCER

Gross Description

- A. Received in formalin labeled with the patient's name and "tissue over prostate" is a yellow, fibrofatty tissue fragment measuring 3 x 2 cm. No lymph node is grossly identified. The specimen is submitted complete in A1-A3.
- B. Received in formalin labeled with the patient's name and "right extended pelvic lymph node" is a yellow fibrofatty tissue fragment measuring 7 x 7 x 1 cm. The fat is trimmed and eight probable lymph nodes are grossly identified. The largest measures 1 x 0.5 cm and the smallest measures 0.5 x 0.5 cm. The specimen is submitted complete in B1-B2.
- C. Received in formalin labeled with the patient's name and "prostate gland seminal vesicle and vas deferens" is a radical prostatectomy specimen which includes a 47 gram prostate gland with attached seminal vesicle and vas deferens. The prostate gland measures 3.5 x 3.5 x 3.0 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 3 x 1 cm. The right vas measures 5 x 0.6 cm. The left seminal vesicle measures 3.5 x 1.5 cm. The left vas deferens measures 4.5 x 0.5 cm. The inferior prostate

Prepared for

[page 3 of 5]
is sectioned transversely, removed from the rest of the specimen, and sectioned from anterior to posterior parallel to the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no abnormalities. Representative sections submitted as follows: inferior prostate demonstrating apical margin submitted entirely anterior to posterior in C1-C6; bladder resection margin C7-C8; complete section of mid gland anterior C9-C10; posterior C11-C12; complete section of upper third of gland, anterior C13-C14; posterior C15-C16; remainder of the posterior gland submitted in C17-C24; right seminal vesicle and vas deferens C25; left seminal vesicle and vas deferens C26. Also, there are two additional cassettes for research, labeled "tumor" and "normal"

Physicians

Signed Supplemental

C. The case was reviewed along with

After review, it is concluded that the tumor focally penetrates through the capsule of the right posterior prostate.

Surrounding the tumor at this site, a single-cell layer of fibrous tissue is appreciable at the margin. This tumor is best regarded as being completely excised.

The TNM stage of the tumor is revised as:

TNM stage: pT3a, pN0, pMX.

Procedure

- A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.2

Prepared for: _____

[page 4 of 5]
H&E X1
C. AA ROUTINE H&E X1 BLOCK.1
H&E X1
C. AA ROUTINE H&E X1 BLOCK.2
H&E X1
C. AA ROUTINE H&E X1 BLOCK.3
H&E X1
C. AA ROUTINE H&E X1 BLOCK.4
H&E X1
C. AA ROUTINE H&E X1 BLOCK.5
H&E X1
C. AA ROUTINE H&E X1 BLOCK.6
H&E X1
C. AA ROUTINE H&E X1 BLOCK.7
H&E X1
~~C. AA ROUTINE H&E X1 BLOCK.8~~
H&E X1
C. AA ROUTINE H&E X1 BLOCK.9
H&E X1
C. AA ROUTINE H&E X1 BLOCK.10
H&E X1
C. AA ROUTINE H&E X1 BLOCK.11
H&E X1
C. AA ROUTINE H&E X1 BLOCK.12
H&E X1
C. AA ROUTINE H&E X1 BLOCK.13
H&E X1
C. AA ROUTINE H&E X1 BLOCK.14
H&E X1
C. AA ROUTINE H&E X1 BLOCK.15
H&E X1
C. AA ROUTINE H&E X1 BLOCK.16
H&E X1
C. AA ROUTINE H&E X1 BLOCK.17
H&E X1
C. AA ROUTINE H&E X1 BLOCK.18
H&E X1
C. AA ROUTINE H&E X1 BLOCK.19
H&E X1
C. AA ROUTINE H&E X1 BLOCK.20
H&E X1
C. AA ROUTINE H&E X1 BLOCK.21
H&E X1
C. AA ROUTINE H&E X1 BLOCK.22
H&E X1
C. AA ROUTINE H&E X1 BLOCK.23
H&E X1 A RECUTS
C. AA ROUTINE H&E X1 BLOCK.24
H&E X1

Prepared for _____

[page 5 of 5]
C. AA ROUTINE H&E X1 BLOCK.25
H&E X1

C. AA ROUTINE H&E X1 BLOCK.26
H&E X1

Prepared for

Source: NCI Genomic Data Commons file 8e086236-383b-4308-b656-e8968a106a2c (TCGA-J4-A67T.8E3BAF97-3B7F-4B3A-BC88-BACB5A716DFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).